Somatic mutation profile of tumor specimen TARGET-10-PAPAPC-09A (aliquot TARGET-10-PAPAPC-09A-01D) from TARGET case TARGET-10-PAPAPC, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.4 years (873 days).
Specimen TARGET-10-PAPAPC-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b27afd94-4294-4851-a485-d06e1a279b20.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPAPC-14A (Bone Marrow Normal), aliquot TARGET-10-PAPAPC-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/61113df4-d5d4-4852-8c06-21737db562e9

The open-access MAF lists 13 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 1, In Frame Del 1, Frame Shift Ins 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKAP3 | c.1030G>A p.V344I | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.679); catalogued as rs369931580, COSV99961755; called by muse, mutect2, varscan2
- ARHGAP44 | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.884); catalogued as rs760624633, COSV52403188; called by muse, mutect2, varscan2
- CDH22 | c.808G>A p.V270I | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs150488776; called by muse, varscan2
- FLT3 | c.1723C>G p.Q575E | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV54043489; called by muse, mutect2, varscan2
- IGHD2-2 | c.30C>G p.C10W | Missense Mutation (SNP) | VAF 9/12 reads (75%) | catalogued as rs373145986; called by mutect2, varscan2
- PRDM6 | c.1777G>A p.E593K | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs773608431, COSV68337771; called by muse, mutect2, varscan2
- PTPRZ1 | c.5578C>A p.Q1860K | Missense Mutation (SNP) | VAF 4/79 reads (5%) | SIFT tolerated (0.91); PolyPhen benign (0.009); catalogued as COSV66432195; called by muse, mutect2
- TMEM164 | c.784C>T p.L262F (on ENST00000372068 / NM_032227.4; = p.L113F on NM_017698.2) | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs146630087, COSV55813259; called by muse, mutect2, varscan2
- ABCG1 | c.587_588insA p.M196Ifs*47 | Frame Shift Ins (INS) | VAF 18/70 reads (26%) | called by mutect2, pindel, varscan2
- IGHD2-2 | c.25_27del p.L9del | In Frame Del (DEL) | VAF 8/11 reads (73%) | called by mutect2, varscan2
- PORCN | c.137-1G>T p.X46_splice | Splice Site (SNP) | VAF 10/108 reads (9%) | called by muse, mutect2
- TTC6 | c.36T>C p.I12= (on ENST00000267368; = p.I1281= on NM_001310135.3) | Silent (SNP) | VAF 14/36 reads (39%) | called by muse, mutect2, varscan2
- CCDC22 | c.*207G>A | 3'UTR (SNP) | VAF 9/40 reads (23%) | called by muse, mutect2, varscan2
